Somatic mutation profile of tumor specimen TARGET-50-PAJNVE-01A (aliquot TARGET-50-PAJNVE-01A-01D) from TARGET case TARGET-50-PAJNVE, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.2 years (800 days).
Specimen TARGET-50-PAJNVE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52a647a4-2922-4a46-9e92-94788d52d1f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNVE-10A (Blood Derived Normal), aliquot TARGET-50-PAJNVE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1089b394-1347-4bee-b46b-042d22e81d88

The open-access MAF lists 13 somatic variants for this specimen: 13 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 37/40 reads (93%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCL11 | c.94del p.C32Afs*15 | Frame Shift Del (DEL) | VAF 112/285 reads (39%) | catalogued as COSV59924936; called by mutect2, pindel, varscan2
- CDK16 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52094368; called by muse, mutect2, varscan2
- FASTKD3 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753721111, COSV52942626; called by muse, mutect2, varscan2
- MYCBP2 | c.13253G>A p.R4418Q (on ENST00000357337; = p.R4456Q on NM_015057.5) | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs753292229, COSV62014352, COSV62023650; called by muse, mutect2, varscan2
- PPP1CC | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58583140; called by muse, mutect2, varscan2
- RAD50 | c.3577A>G p.T1193A | Missense Mutation (SNP) | VAF 161/175 reads (92%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV54749717; called by muse, mutect2, varscan2
- RALGPS2 | c.1650A>T p.Q550H | Missense Mutation (SNP) | VAF 760/1387 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV62678396; called by muse, mutect2, varscan2
- ZNF711 | c.609C>G p.Y203* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV52152826, COSV99341757; called by muse, mutect2, varscan2
- ACP3 | c.419_430del p.P140_V143del | In Frame Del (DEL) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- CPXM2 | c.1970_1986del p.P657Rfs*5 | Frame Shift Del (DEL) | VAF 151/1116 reads (14%) | called by mutect2, pindel
- FOXC1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NWD2 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
